CGCI case HTMCP-03-06-02176 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9453db51-fff8-4a78-a29c-bb9151e9bd2a

Demographics
Sex at birth: female; Race: black or african american; Age at index: 54 years; Vital status: Dead; Days to death: 521 days (1.4 years).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; AJCC clinical T: T3b; AJCC clinical N: N1; AJCC clinical M: M0; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 521 days (1.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Not Otherwise Specified; Initial disease status: Initial Diagnosis; Days to treatment start: 27 days; Days to treatment end: 152 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 68 days; Days to treatment end: 68 days; Treatment dose: 8; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Treatment dose: 6; Treatment outcome: Complete Response; Chemo concurrent to radiation: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 800; Treatment outcome: Complete Response; Treatment anatomic sites: Pelvis.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 319 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Vulva, NOS; Days to recurrence: 319 days.
- Days to follow up: 463 days (1.3 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 521.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 45.9 kg; Height: 175 cm; BMI: 15; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Day 0: Pregnancy outcome: Miscarriage.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02176-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02176-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02176-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 8; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 9; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Adenocarcinoma, Not Otherwise Specified; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Negative.
- Follow-up form 1: Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation treatment reason not completed: Adverse event/complications; Radiation therapy xrt type: External beam radiation.
- Follow-up form 1, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 105; Pharmaceutical treatment dose units: mg; Chemo concurrent fractions total: 6.
- Follow-up form 1, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: Vulva; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Single Agent Therapy (please specify); Single agent therapy: Other Single Agent Therapy (please specify); Pharma adjuvant cycles count: 6.
- Treatments, Treatment 2: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 8.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02176-01A-01R-6194:
- % tumour top: 80
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02176-01A-01D-6194:
- % tumour top: 80
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02176-10A-01D-6194:
- % tumour top: 0
- % tumour bottom: 0
